Somatic mutation profile of cancer-model specimen HCM-CSHL-0698-C06-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0698-C06-85A-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0698-C06, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage II.
Specimen HCM-CSHL-0698-C06-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa8a628b-aa69-4550-8f52-d4ea95708223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0698-C06-10A (Blood Derived Normal), aliquot HCM-CSHL-0698-C06-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32a06a5d-e4c8-482d-9e62-b199b6693d25

The open-access MAF lists 524 somatic variants for this specimen: 376 protein-altering or splice-affecting, 134 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 134, Nonsense Mutation 31, Intron 6, 3'UTR 4, Frame Shift Del 2, RNA 2, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 151/343 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 139/687 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 374/376 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM9 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 378/378 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs756115024; called by muse, mutect2, varscan2
- ADAMTS5 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 210/211 reads (100%) | catalogued as rs963577631; called by muse, mutect2, varscan2
- ADAR | c.1359G>C p.Q453H | Missense Mutation (SNP) | VAF 152/682 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99425659; called by muse, mutect2, varscan2
- ADNP | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 286/458 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62426507; called by muse, mutect2, varscan2
- ALOX15 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 341/450 reads (76%) | catalogued as rs11870258; called by muse, mutect2, varscan2
- AMBRA1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 98/385 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs757353536; called by muse, mutect2, varscan2
- AMER3 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 231/418 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.23); catalogued as COSV58470812; called by muse, mutect2, varscan2
- AMER3 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 220/427 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1178678040; called by muse, mutect2, varscan2
- ANAPC2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 161/607 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs186490734, COSV59244143; called by muse, mutect2, varscan2
- ANKRD36C | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 93/187 reads (50%) | catalogued as COSV101511134; called by muse, mutect2, varscan2
- AP1G2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs759104775, COSV55337301, COSV55339360; called by muse, varscan2
- AP4E1 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1457632533; called by muse, mutect2, varscan2
- ARHGAP44 | c.2418G>C p.K806N | Missense Mutation (SNP) | VAF 243/337 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs760690525; called by muse, mutect2, varscan2
- ASXL3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs201305732, COSV52462582; called by muse, mutect2, varscan2
- ATP2A1 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 141/480 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100706912; called by muse, mutect2, varscan2
- AUTS2 | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV61383273; called by muse, mutect2, varscan2
- BAZ1A | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 175/359 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1466489502, COSV100701154, COSV62408893; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 408/649 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- C10orf88 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1227944522; called by muse, mutect2, varscan2
- C19orf18 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100071867; called by muse, mutect2, varscan2
- C1orf112 | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 193/369 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV53676865; called by muse, mutect2, varscan2
- C3 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 210/336 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs773744747, COSV55576057; called by muse, mutect2, varscan2
- C5orf15 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 353/355 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as rs147810691; called by muse, mutect2, varscan2
- CACHD1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 111/171 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs370697878; called by muse, mutect2, varscan2
- CACHD1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV51558404; called by muse, mutect2, varscan2
- CCDC88A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 109/778 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); catalogued as COSV55065188, COSV55068576; called by muse, mutect2, varscan2
- CCDC88C | c.5888C>G p.S1963* | Nonsense Mutation (SNP) | VAF 145/610 reads (24%) | catalogued as COSV57795975; called by muse, mutect2, varscan2
- CCNB3 | c.2048C>G p.T683S | Missense Mutation (SNP) | VAF 230/231 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV99328774; called by muse, mutect2, varscan2
- CDC42SE1 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 59/722 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61785591; called by muse, mutect2
- CDON | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 252/253 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141611214; called by muse, mutect2, varscan2
- CEP290 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs376425111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP89 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 207/772 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59867170; called by muse, varscan2
- CHD2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59122823; called by muse, mutect2
- CHRM3 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 77/451 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55104757; called by muse, mutect2, varscan2
- COBL | c.3332C>G p.S1111C | Missense Mutation (SNP) | VAF 219/761 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54359510; called by muse, mutect2, varscan2
- COL11A1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as rs762173332; called by muse, mutect2, varscan2
- CORIN | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1183185639, COSV56692389; called by muse, mutect2, varscan2
- CPD | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV56712280; called by muse, mutect2
- CPLANE1 | c.9425C>G p.S3142C | Missense Mutation (SNP) | VAF 69/420 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV57066817; called by muse, mutect2, varscan2
- CRELD1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 222/466 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs115049151; called by muse, mutect2, varscan2
- CTCFL | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 196/625 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429635968, COSV54778791; called by muse, mutect2, varscan2
- CTDSP1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 240/421 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs762615334, COSV51919859; called by muse, mutect2, varscan2
- CTTNBP2 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.638); catalogued as COSV99352904; called by muse, mutect2, varscan2
- CUX1 | c.472G>A p.E158K (on ENST00000292535 / NM_181552.4; = p.E169K on NM_001913.5) | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs138328289; called by muse, mutect2, varscan2
- DAXX | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 503/504 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as rs375524506, COSV56466992; called by muse, mutect2, varscan2
- DHX36 | c.2638G>C p.D880H | Missense Mutation (SNP) | VAF 73/682 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs761280991, COSV57676471; called by muse, mutect2, varscan2
- DMRTB1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 193/567 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1372527767; called by muse, mutect2, varscan2
- DNAH11 | c.5611C>G p.L1871V | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370425262, COSV100177677; called by muse, mutect2, varscan2
- DPP4 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 103/199 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100858892; called by muse, mutect2, varscan2
- DYNC1H1 | c.6536G>A p.R2179Q | Missense Mutation (SNP) | VAF 187/391 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs1222784464; called by muse, mutect2, varscan2
- ETV1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 132/488 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs936225135, COSV54137018, COSV54149079; called by muse, mutect2
- EYS | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 340/340 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV65459424; called by muse, mutect2, varscan2
- FAM135A | c.3554C>G p.S1185C (on ENST00000370479 / NM_001351599.1; = p.S972C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.798); catalogued as rs762318584; called by muse, mutect2, varscan2
- FAM160B1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 271/394 reads (69%) | catalogued as COSV65089771; called by muse, mutect2, varscan2
- FBXO10 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 367/484 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs750043481; called by muse, mutect2, varscan2
- FCRL5 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 53/591 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.103); catalogued as rs144683444; called by muse, mutect2
- FSIP2 | c.8038dup p.T2680Nfs*9 | Frame Shift Ins (INS) | VAF 90/232 reads (39%) | catalogued as rs755234663; called by mutect2, varscan2
- FTSJ3 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV63791236; called by muse, mutect2, varscan2
- GARNL3 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 250/344 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV100149841; called by muse, varscan2
- GCNT7 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 336/542 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as rs561869700; called by muse, mutect2, varscan2
- GPC2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 155/403 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs199607762; called by muse, mutect2, varscan2
- GPR141 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 192/691 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV57731421; called by muse, mutect2, varscan2
- HCFC1R1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as rs762463939, COSV50187156, COSV99560786; called by muse, mutect2, varscan2
- HSCB | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs757079729; called by muse, mutect2, varscan2
- HTT | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100751293; called by muse, mutect2, varscan2
- IBTK | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.9); catalogued as rs752460489, COSV100089750, COSV60391150; called by muse, mutect2, varscan2
- IFT80 | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 38/509 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV100424653; called by muse, mutect2
- IMPG2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 143/891 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1255424680; called by muse, mutect2, varscan2
- IQCG | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 107/588 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99502210; called by muse, mutect2, varscan2
- ITGA1 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 171/536 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50901540; called by muse, mutect2, varscan2
- KIAA0753 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 230/308 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs1301909491; called by muse, varscan2
- KIF16B | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV61702382, COSV61705940; called by muse, varscan2
- KIR2DL1 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 183/495 reads (37%) | catalogued as COSV99382587; called by muse, varscan2
- KLHL23 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV55869364; called by muse, varscan2
- KMT2C | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV51521369; called by muse, mutect2, varscan2
- KNTC1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs760669670, COSV61082231; called by muse, mutect2, varscan2
- LBR | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 232/466 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs1190304682; called by muse, mutect2, varscan2
- LONP1 | c.2100C>G p.I700M | Missense Mutation (SNP) | VAF 197/345 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV61501811; called by muse, mutect2, varscan2
- LONP1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 213/336 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV62260856; called by muse, mutect2, varscan2
- LRCH4 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 433/434 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs937359122; called by muse, mutect2, varscan2
- LRRC46 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 258/434 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1178902936; called by muse, mutect2, varscan2
- LY75 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1324695179; called by muse, mutect2, varscan2
- MAGI3 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 182/296 reads (61%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56841546; called by muse, mutect2, varscan2
- MAMDC4 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 330/474 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776930358; called by muse, mutect2, varscan2
- MAN1A2 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 166/241 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62977745; called by muse, mutect2, varscan2
- MEGF11 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 167/829 reads (20%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.523); catalogued as rs767725663, COSV56548778; called by muse, mutect2, varscan2
- MFN1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 117/1031 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.301); catalogued as rs895517753; called by muse, mutect2, varscan2
- MFSD11 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs140463423; called by muse, mutect2, varscan2
- MMP21 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 130/529 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1410859368; called by muse, mutect2, varscan2
- MRE11 | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 197/198 reads (99%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV60577583; called by muse, mutect2, varscan2
- MRGPRD | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 228/3815 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100483089; called by muse, mutect2
- MS4A14 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 158/423 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55738258; called by muse, mutect2, varscan2
- NADK2 | c.563C>G p.S188C (on ENST00000381937 / NM_001085411.3; = p.S25C on NM_153013.4) | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56934962; called by muse, mutect2, varscan2
- NDUFS2 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 42/447 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57155654; called by muse, mutect2
- NDUFV1 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 264/699 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs761356156; called by muse, mutect2, varscan2
- NF1 | c.3449C>T p.S1150L | Missense Mutation (SNP) | VAF 93/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM062911, COSV62192927, COSV62204872; called by muse, mutect2, varscan2
- NOL4 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52362998; called by muse, mutect2, varscan2
- NOTO | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 136/924 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1329327278, COSV68260071; called by muse, mutect2, varscan2
- NR2F6 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 161/478 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1244300442; called by muse, varscan2
- NRXN1 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 482/1102 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV68015235; called by muse, mutect2, varscan2
- NUP85 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs776562028; called by muse, mutect2, varscan2
- OPN4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 129/550 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs375395379; called by muse, mutect2, varscan2
- OR5B2 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 178/441 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV56909162; called by muse, mutect2, varscan2
- PCDH15 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 198/277 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.4); catalogued as rs776227894; called by muse, mutect2, varscan2
- PCDHGA6 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 189/368 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs1463444937, COSV53981920; called by muse, mutect2, varscan2
- PDCD11 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 322/427 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138971174; called by muse, mutect2, varscan2
- PEG3 | c.3732G>A p.M1244I | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV55625666; called by muse, mutect2, varscan2
- PER1 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 281/283 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766369146; called by muse, mutect2, varscan2
- PICK1 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 235/769 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57636917; called by muse, mutect2, varscan2
- PIK3CA | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 71/640 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55992774; called by muse, mutect2, varscan2
- PKN3 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 265/358 reads (74%) | catalogued as rs1260163894; called by muse, mutect2, varscan2
- PLCE1 | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53349810; called by muse, mutect2, varscan2
- PLEKHM1 | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 96/581 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373939822; called by muse, mutect2, varscan2
- PLS1 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 74/970 reads (8%) | catalogued as COSV100538102, COSV61832682; called by muse, mutect2
- PLXNA1 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 582/806 reads (72%) | catalogued as rs371434286, COSV52524439; called by muse, mutect2, varscan2
- PLXNB2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 164/1021 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs554117465, COSV63784154; called by muse, mutect2, varscan2
- POLH | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 374/375 reads (100%) | catalogued as rs761688287; called by muse, varscan2
- POLH | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 216/216 reads (100%) | catalogued as COSV100947747; called by muse, varscan2
- PRMT7 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 88/517 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as rs200093947; called by muse, mutect2, varscan2
- PRR14L | c.3956C>G p.S1319C | Missense Mutation (SNP) | VAF 98/568 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV57883891; called by muse, mutect2, varscan2
- RABEP1 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 265/384 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99336940; called by muse, mutect2, varscan2
- RABGEF1 | c.669G>C p.Q223H (on ENST00000439720 / NM_001287061.2; = p.Q210H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53164730; called by muse, mutect2, varscan2
- RESF1 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1265872561; called by muse, mutect2, varscan2
- RFPL3 | c.148C>T p.P50S (on ENST00000249007 / NM_001098535.1; = p.P21S on NM_006604.2) | Missense Mutation (SNP) | VAF 286/940 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99967145; called by muse, mutect2, varscan2
- RPRD2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 54/712 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs782509575; called by muse, mutect2
- SALL1 | c.3658G>C p.D1220H | Missense Mutation (SNP) | VAF 190/509 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51753346, COSV51763650; called by muse, varscan2
- SCN3A | c.2189G>A p.W730* | Nonsense Mutation (SNP) | VAF 95/189 reads (50%) | catalogued as rs1409142141; called by muse, mutect2, varscan2
- SH3D21 | c.760C>T p.R254W (on ENST00000453908 / NM_001162530.2; = p.R143W on NM_024676.5) | Missense Mutation (SNP) | VAF 205/305 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs764214065; called by muse, mutect2, varscan2
- SMPD2 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 331/331 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs368724627; called by muse, varscan2
- SNAP23 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 94/298 reads (32%) | catalogued as COSV51041024, COSV51041778; called by muse, mutect2, varscan2
- SNAPC4 | c.4172C>T p.S1391L | Missense Mutation (SNP) | VAF 94/535 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1341064406; called by muse, mutect2, varscan2
- SOCS5 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 265/638 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1386239400, COSV60604932; called by muse, mutect2, varscan2
- SSC5D | c.3955C>T p.P1319S | Missense Mutation (SNP) | VAF 165/527 reads (31%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.012); catalogued as rs967136530; called by muse, mutect2, varscan2
- ST6GAL2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 185/406 reads (46%) | PolyPhen benign (0.017); catalogued as COSV99080769; called by muse, mutect2, varscan2
- STAG1 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 181/746 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.515); catalogued as COSV52611801; called by muse, varscan2
- SVIL | c.5372C>T p.T1791M (on ENST00000355867 / NM_021738.3; = p.T1365M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/286 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs746902705, COSV63442379; called by muse, mutect2, varscan2
- TAAR6 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51582642; called by muse, mutect2, varscan2
- TAF7L | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV63300934; called by muse, mutect2
- TARBP1 | c.4192C>G p.Q1398E | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381465377, COSV50200144; called by muse, mutect2, varscan2
- TBC1D14 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs1054532986; called by muse, mutect2, varscan2
- TBRG4 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 72/546 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51834264; called by muse, mutect2, varscan2
- TC2N | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 103/413 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as COSV61747855; called by muse, mutect2, varscan2
- TES | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV64041922; called by muse, mutect2, varscan2
- TFRC | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 158/697 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs753887498; called by muse, mutect2, varscan2
- THOC6 | c.98C>A p.S33* | Nonsense Mutation (SNP) | VAF 232/480 reads (48%) | catalogued as COSV99560623; called by muse, varscan2
- TMC7 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1355238435, COSV58583514; called by muse, mutect2, varscan2
- TMEM154 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 252/319 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58591383; called by muse, mutect2, varscan2
- TMPRSS9 | c.959C>T p.A320V (on ENST00000648592; = p.A286V on NM_182973.2) | Missense Mutation (SNP) | VAF 275/429 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.299); catalogued as rs746335015, COSV60225361; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 158/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373705439; called by muse, mutect2, varscan2
- TRIOBP | c.4138G>C p.E1380Q | Missense Mutation (SNP) | VAF 132/798 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV60378318; called by muse, mutect2, varscan2
- TRPV3 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 155/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753815254, COSV56793867; called by muse, mutect2, varscan2
- TTN | c.7567G>A p.E2523K (on ENST00000591111; = p.E2477K on NM_003319.4) | Missense Mutation (SNP) | VAF 109/262 reads (42%) | PolyPhen benign (0.215); catalogued as COSV60001353; called by muse, mutect2, varscan2
- UGT1A5 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291086898, COSV100529843; called by muse, mutect2, varscan2
- UMOD | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 134/263 reads (51%) | catalogued as COSV56775574; called by muse, mutect2, varscan2
- UNC13C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 139/366 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs565877113, COSV52873149, COSV99509498; called by muse, mutect2, varscan2
- VASP | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 117/199 reads (59%) | catalogued as rs568311975, COSV55606531; called by mutect2, varscan2
- ZFP30 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 200/2672 reads (7%) | catalogued as rs972640897; called by muse, mutect2
- ZMYND15 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 363/488 reads (74%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV52641117; called by muse, mutect2, varscan2
- ZNF257 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as rs1173142653, COSV101448112; called by muse, mutect2, varscan2
- ZNF385D | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 126/243 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV55766442; called by muse, mutect2, varscan2
- ZNF560 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 185/318 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV56870078; called by muse, mutect2, varscan2
- ZNF583 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52401666; called by muse, mutect2, varscan2
- ZNF823 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.965); catalogued as COSV100362501, COSV57872242; called by muse, mutect2, varscan2
- ZNF875 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 208/2458 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs755355980; called by muse, mutect2
- ZPLD1 | c.1010T>A p.V337E (on ENST00000466937 / NM_001329788.1; = p.V353E on NM_175056.2) | Missense Mutation (SNP) | VAF 45/921 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV60355578; called by muse, mutect2
- ABCB10 | c.1353C>G p.F451L | Missense Mutation (SNP) | VAF 161/329 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ABHD6 | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AC099489.1 | c.5177C>G p.P1726R | Missense Mutation (SNP) | VAF 133/291 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AC245033.1 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 128/355 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACRBP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 122/697 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ACTN2 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 153/400 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ACTR1B | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADGRA3 | c.2366G>C p.R789T | Missense Mutation (SNP) | VAF 197/252 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ADGRV1 | c.10363G>C p.E3455Q | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGAP4 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 71/435 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AKAP13 | c.2807C>G p.S936C | Missense Mutation (SNP) | VAF 152/443 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- AKNA | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 239/312 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ALKBH5 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 137/530 reads (26%) | called by mutect2, varscan2
- ALOX5 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 237/326 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD11 | c.6623C>T p.S2208L | Missense Mutation (SNP) | VAF 255/673 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36C | c.4085C>G p.S1362C | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ANKRD55 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 82/571 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APOB | c.8713G>T p.D2905Y | Missense Mutation (SNP) | VAF 238/991 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- AQR | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 196/500 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ARFGEF1 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARHGAP45 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ARHGEF11 | c.2292G>A p.M764I | Missense Mutation (SNP) | VAF 70/726 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ATL1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 71/297 reads (24%) | called by muse, mutect2, varscan2
- BAZ1B | c.1897A>G p.T633A | Missense Mutation (SNP) | VAF 202/464 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BCL9 | c.3357C>G p.I1119M | Missense Mutation (SNP) | VAF 97/738 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- BOD1L1 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- C11orf95 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 396/987 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C12orf71 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3orf85 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 106/504 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C3orf85 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- CATSPERG | c.2670C>A p.F890L | Missense Mutation (SNP) | VAF 234/5365 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- CD79B | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 125/646 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CDKL2 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR3 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CES5A | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 232/615 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CETN1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 173/927 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CFAP44 | c.4333G>C p.E1445Q | Missense Mutation (SNP) | VAF 69/395 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CHSY3 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 286/567 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CHSY3 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 285/567 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CIC | c.35C>G p.S12* | Nonsense Mutation (SNP) | VAF 231/367 reads (63%) | called by muse, mutect2, varscan2
- CRACDL | c.1922G>C p.G641A | Missense Mutation (SNP) | VAF 480/480 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CRTC2 | c.975_991del p.G326Tfs*145 | Frame Shift Del (DEL) | VAF 112/484 reads (23%) | called by mutect2, pindel, varscan2
- CTNND2 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 94/684 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- CYFIP1 | c.2167C>G p.L723V | Missense Mutation (SNP) | VAF 186/529 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYSLTR1 | c.669A>T p.K223N | Missense Mutation (SNP) | VAF 235/236 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DCDC2 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 21/643 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2
- DCP2 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 95/153 reads (62%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DDX19B | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 208/337 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DGCR8 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 73/508 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DGUOK | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP1 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 207/968 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DNAH11 | c.10585G>A p.E3529K | Missense Mutation (SNP) | VAF 102/383 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1014G>C p.L338F | Missense Mutation (SNP) | VAF 110/1120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EFCAB8 | c.3864C>G p.F1288L | Missense Mutation (SNP) | VAF 159/424 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ENOPH1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ESRRA | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 239/642 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESRRA | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 298/777 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, varscan2
- ESRRA | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.033); called by muse, varscan2
- EXPH5 | c.5147C>A p.S1716Y | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FAM114A1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 210/293 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM135A | c.2593C>G p.L865V (on ENST00000370479 / NM_001351599.1; = p.L652V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM160B1 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- FAM71F2 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FAM98C | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 264/5344 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- FAT1 | c.8919G>T p.Q2973H | Missense Mutation (SNP) | VAF 317/402 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FBF1 | c.1835G>T p.G612V (on ENST00000586717; = p.G626V on NM_001319193.1) | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FBF1 | c.1834G>T p.G612W (on ENST00000586717; = p.G626W on NM_001319193.1) | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- FBF1 | c.1376C>T p.S459F (on ENST00000586717; = p.S473F on NM_001319193.1) | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- FMNL3 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FMNL3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 253/539 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FSIP2 | c.14410C>T p.Q4804* | Nonsense Mutation (SNP) | VAF 94/221 reads (43%) | called by muse, mutect2, varscan2
- FTSJ3 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 107/503 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- GANC | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 144/401 reads (36%) | called by muse, mutect2, varscan2
- GATAD2B | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 61/720 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- GHRHR | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 233/834 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLB1L | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNL1 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- GOLGA6L4 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 137/693 reads (20%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- GSAP | c.1856dup p.L619Ffs*13 | Frame Shift Ins (INS) | VAF 120/376 reads (32%) | called by mutect2, pindel, varscan2
- HDC | c.1842C>G p.I614M | Missense Mutation (SNP) | VAF 223/596 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- HEG1 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 175/691 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HPS5 | c.1468G>C p.E490Q (on ENST00000349215 / NM_181507.2; = p.E376Q on NM_007216.4) | Missense Mutation (SNP) | VAF 233/459 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HSPBAP1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 156/640 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IFT140 | c.3188C>G p.S1063C | Missense Mutation (SNP) | VAF 181/398 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGKV1D-42 | c.62G>T p.R21I | Missense Mutation (SNP) | VAF 150/833 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- IL4I1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1270G>C p.E424Q (on ENST00000485419 / NM_001197113.1; = p.E348Q on NM_014575.3) | Missense Mutation (SNP) | VAF 141/645 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KBTBD11 | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- KCTD17 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 185/671 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIAA1328 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- KMO | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNL1 | c.2249C>G p.S750C (on ENST00000346991 / NM_170589.5; = p.S724C on NM_144508.5) | Missense Mutation (SNP) | VAF 161/458 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- KPNA7 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LAMA3 | c.4919C>G p.S1640C | Missense Mutation (SNP) | VAF 130/403 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LCMT2 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 246/682 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LOXHD1 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- LRCH4 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 444/444 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- LRGUK | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 75/460 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRP11 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 443/446 reads (99%) | SIFT tolerated (0.51); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRRD1 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 122/323 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LSS | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LZTS2 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 382/382 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACF1 | c.14389C>A p.L4797I (on ENST00000372915; = p.L2730I on NM_012090.5) | Missense Mutation (SNP) | VAF 92/250 reads (37%) | called by muse, varscan2
- MAMDC4 | c.3013C>G p.R1005G (on ENST00000445819; = p.R926G on NM_206920.3) | Missense Mutation (SNP) | VAF 427/569 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- MAP3K13 | c.2052C>A p.S684R | Missense Mutation (SNP) | VAF 271/1355 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MAP6D1 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 272/1431 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MAPK8IP1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 190/668 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, varscan2
- MARK1 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2663G>C p.R888T | Missense Mutation (SNP) | VAF 199/451 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MTCL1 | c.5389G>C p.E1797Q (on ENST00000306329 / NM_001378206.1; = p.E1478Q on NM_015210.4) | Missense Mutation (SNP) | VAF 263/1170 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MTMR4 | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 226/375 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTPAP | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.12501C>G p.F4167L (on ENST00000379442; = p.F4024L on NM_001164462.1) | Missense Mutation (SNP) | VAF 170/2623 reads (6%) | SIFT tolerated (0.18); called by muse, mutect2
- MYT1L | c.2506G>C p.D836H | Missense Mutation (SNP) | VAF 135/592 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- NACC1 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 184/280 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NAE1 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NAGK | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 68/471 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRC5 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 250/718 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2
- NOL4L | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 123/372 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR2V1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- OR4C11 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PAPOLG | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PARD3B | c.2704G>C p.E902Q (on ENST00000406610 / NM_001302769.2; = p.E833Q on NM_057177.7) | Missense Mutation (SNP) | VAF 180/347 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCOLCE2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 174/988 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PHLPP2 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 151/435 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PI4KA | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 78/499 reads (16%) | called by muse, mutect2, varscan2
- PITPNC1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD3 | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 147/484 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG2 | c.3613G>C p.D1205H | Missense Mutation (SNP) | VAF 300/5928 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2
- PLIN4 | c.1217C>T p.T406I (on ENST00000301286; = p.T421I on NM_001367868.2) | Missense Mutation (SNP) | VAF 15/504 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2
- POLR3A | c.4059G>T p.M1353I | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, varscan2
- POLR3A | c.3643G>C p.D1215H | Missense Mutation (SNP) | VAF 84/383 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- POLR3A | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLRMT | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 106/355 reads (30%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPIP5K2 | c.2759A>T p.E920V | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PPP1R8 | c.691G>T p.V231F (on ENST00000311772 / NM_014110.5; = p.V7F on NM_002713.4) | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- PPP1R9A | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PRKCG | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 177/265 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMB5 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 45/505 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSMD2 | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 66/762 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PSPC1 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 311/501 reads (62%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PTGES3 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- PUS7L | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PWWP3A | c.166G>A p.E56K (on ENST00000627377; = p.E55K on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RAB11FIP1 | c.2990G>A p.G997E | Missense Mutation (SNP) | VAF 524/525 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, varscan2
- RAB11FIP1 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 435/435 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.052); called by muse, varscan2
- RAB3A | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 159/254 reads (63%) | called by muse, mutect2, varscan2
- RALGDS | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 431/565 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM20 | c.3683G>C p.*1228Sext*33 | Nonstop Mutation (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- RETSAT | c.1791G>T p.K597N | Missense Mutation (SNP) | VAF 133/883 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RHBDL1 | c.887C>A p.S296Y (on ENST00000219551 / NM_001318733.2; = p.S231Y on NM_001278720.2) | Missense Mutation (SNP) | VAF 115/489 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ROBO2 | c.1520-1G>A p.X507_splice | Splice Site (SNP) | VAF 98/98 reads (100%) | called by muse, mutect2, varscan2
- ROCK2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPS6KB1 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RSPO2 | c.249T>G p.Y83* | Nonsense Mutation (SNP) | VAF 93/276 reads (34%) | called by muse, mutect2, varscan2
- SCN10A | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 232/447 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN10A | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCYL3 | c.1606G>A p.E536K (on ENST00000367770; = p.E482K on NM_020423.7) | Missense Mutation (SNP) | VAF 99/391 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SEL1L | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SELENBP1 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 68/672 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SEMA6C | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 302/919 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SLC27A1 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SLC2A2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 148/731 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOCS5 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 320/746 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SPG11 | c.6370C>T p.H2124Y | Missense Mutation (SNP) | VAF 89/507 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- SRGAP1 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 94/555 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SSC4D | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 462/462 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD4 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STN1 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 17/489 reads (3%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); called by muse, mutect2
- TAS2R10 | c.237_241del p.L80* | Frame Shift Del (DEL) | VAF 313/326 reads (96%) | called by mutect2, pindel, varscan2
- TCAIM | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TCEA3 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 159/262 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TERB1 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- THADA | c.4125G>C p.M1375I | Missense Mutation (SNP) | VAF 194/792 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- TNFRSF1A | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 530/644 reads (82%) | called by muse, mutect2, varscan2
- TPM1 | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAF7 | c.1627-1G>A p.X543_splice | Splice Site (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- TRAPPC6A | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 214/299 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TRIM5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 243/470 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTF2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 171/292 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- UBXN7 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 96/501 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- UGT2A2 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- UNC93B1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 266/820 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- USP34 | c.9751G>A p.E3251K | Missense Mutation (SNP) | VAF 218/532 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VPS13B | c.5224C>G p.Q1742E | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VPS41 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 96/718 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- WDFY2 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN1 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 62/1084 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- ZFAND6 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP28 | c.1214C>A p.S405* | Nonsense Mutation (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- ZFP36 | c.986C>G p.S329C (on ENST00000594442; = p.S323C on NM_003407.5) | Missense Mutation (SNP) | VAF 168/3554 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFPL1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 392/668 reads (59%) | called by muse, varscan2
- ZMIZ1 | c.2559G>A p.M853I | Missense Mutation (SNP) | VAF 317/448 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ZMYND15 | c.1636G>A p.D546N (on ENST00000433935 / NM_001136046.3; = p.D507N on NM_032265.2) | Missense Mutation (SNP) | VAF 262/349 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF141 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 199/262 reads (76%) | called by muse, mutect2, varscan2
- ZNF45 | c.1017G>C p.K339N | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF530 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF569 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 64/2534 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- ZNF573 | c.451C>G p.L151V (on ENST00000536220 / NM_001172692.1; = p.L93V on NM_152360.3) | Missense Mutation (SNP) | VAF 157/2422 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.053); called by muse, mutect2
- ZNF584 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 175/258 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF609 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 162/484 reads (33%) | called by muse, mutect2, varscan2
- ZNF814 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 164/528 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, varscan2
- ZNF814 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 206/250 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, varscan2
- ZNF875 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 256/3740 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ZP3 | c.743C>T p.S248F (on ENST00000394857 / NM_001110354.2; = p.S197F on NM_007155.6) | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZSWIM4 | c.259T>A p.Y87N | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2
- ABHD17A | c.36C>T p.L12= | Silent (SNP) | VAF 182/360 reads (51%) | catalogued as COSV51752366, COSV99171238; called by muse, varscan2
- AGO2 | c.384C>T p.F128= | Silent (SNP) | VAF 85/419 reads (20%) | called by muse, mutect2, varscan2
- ALLC | c.213C>T p.V71= | Silent (SNP) | VAF 154/749 reads (21%) | catalogued as COSV52993714; called by muse, mutect2, varscan2
- ANKRD11 | c.5373C>G p.V1791= | Silent (SNP) | VAF 207/503 reads (41%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4452G>T p.L1484= | Silent (SNP) | VAF 233/722 reads (32%) | called by muse, mutect2, varscan2
- APLP1 | c.309G>A p.Q103= | Silent (SNP) | VAF 223/818 reads (27%) | catalogued as rs1343705737; called by muse, mutect2, varscan2
- AR | c.1425G>A p.A475= | Silent (SNP) | VAF 193/196 reads (98%) | catalogued as rs1435687966; called by muse, mutect2, varscan2
- ATP13A5 | c.3435C>T p.I1145= | Silent (SNP) | VAF 86/859 reads (10%) | catalogued as COSV99290636; called by muse, mutect2
- AXL | c.702C>G p.V234= | Silent (SNP) | VAF 248/384 reads (65%) | catalogued as rs987881778; called by muse, mutect2, varscan2
- C10orf71 | c.36C>T p.F12= | Silent (SNP) | VAF 77/323 reads (24%) | called by muse, mutect2, varscan2
- C11orf95 | c.1425C>T p.L475= | Silent (SNP) | VAF 294/793 reads (37%) | catalogued as rs1205564771; called by muse, varscan2
- C12orf65 | c.138G>A p.K46= | Silent (SNP) | VAF 185/407 reads (45%) | catalogued as COSV99474091; called by muse, mutect2, varscan2
- CABIN1 | c.1689C>T p.S563= | Silent (SNP) | VAF 64/525 reads (12%) | called by muse, mutect2, varscan2
- CACNA1E | c.1668C>A p.V556= | Silent (SNP) | VAF 157/734 reads (21%) | called by muse, mutect2, varscan2
- CAPSL | c.306C>T p.L102= | Silent (SNP) | VAF 49/312 reads (16%) | called by muse, mutect2, varscan2
- CCDC191 | c.771G>A p.R257= | Silent (SNP) | VAF 186/837 reads (22%) | called by muse, mutect2, varscan2
- CCR6 | c.204G>A p.V68= | Silent (SNP) | VAF 384/384 reads (100%) | called by muse, mutect2, varscan2
- CDH18 | c.1908G>C p.L636= | Silent (SNP) | VAF 172/382 reads (45%) | called by muse, mutect2, varscan2
- CELSR1 | c.246G>A p.A82= | Silent (SNP) | VAF 266/922 reads (29%) | called by muse, mutect2, varscan2
- CIC | c.1443C>T p.Y481= | Silent (SNP) | VAF 309/495 reads (62%) | catalogued as rs1214320973; called by muse, mutect2, varscan2
- CIITA | c.2142A>G p.Q714= | Silent (SNP) | VAF 123/541 reads (23%) | catalogued as rs188988714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND2 | c.1311C>G p.L437= | Silent (SNP) | VAF 324/559 reads (58%) | called by muse, mutect2, varscan2
- CTXN1 | c.117C>G p.L39= | Silent (SNP) | VAF 326/489 reads (67%) | catalogued as rs376165674; called by muse, mutect2, varscan2
- CYP46A1 | c.24C>G p.L8= | Silent (SNP) | VAF 89/383 reads (23%) | catalogued as rs894318358; called by muse, mutect2, varscan2
- CYP4A22 | c.1488G>A p.L496= | Silent (SNP) | VAF 162/445 reads (36%) | called by muse, mutect2, varscan2
- DCST1 | c.549G>A p.L183= | Silent (SNP) | VAF 136/455 reads (30%) | called by muse, mutect2, varscan2
- DLGAP4 | c.2659C>T p.L887= (on ENST00000339266 / NM_001365621.1; = p.L884= on NM_014902.6) | Silent (SNP) | VAF 226/711 reads (32%) | called by muse, mutect2, varscan2
- E4F1 | c.1980C>T p.I660= | Silent (SNP) | VAF 113/467 reads (24%) | catalogued as rs771704183, COSV57038401; called by muse, mutect2, varscan2
- EPHA3 | c.1167C>T p.L389= | Silent (SNP) | VAF 164/165 reads (99%) | called by muse, mutect2, varscan2
- FAM111B | c.1551C>T p.F517= | Silent (SNP) | VAF 214/517 reads (41%) | catalogued as COSV59112626; called by muse, mutect2, varscan2
- FAM151A | c.36C>T p.V12= | Silent (SNP) | VAF 120/346 reads (35%) | catalogued as COSV100157073; called by muse, mutect2, varscan2
- FER | c.1947G>C p.L649= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as COSV55291837, COSV99814144; called by muse, mutect2, varscan2
- FOXD4L5 | c.831C>G p.V277= | Silent (SNP) | VAF 307/912 reads (34%) | called by muse, mutect2, varscan2
- FOXD4L6 | c.831C>G p.V277= | Silent (SNP) | VAF 114/499 reads (23%) | called by muse, mutect2, varscan2
- FOXE1 | c.156G>A p.G52= | Silent (SNP) | VAF 163/679 reads (24%) | called by muse, mutect2, varscan2
- GASK1A | c.1443C>G p.V481= | Silent (SNP) | VAF 115/246 reads (47%) | called by muse, mutect2, varscan2
- GNA13 | c.993G>A p.R331= | Silent (SNP) | VAF 96/515 reads (19%) | called by muse, mutect2, varscan2
- GNL1 | c.1341G>A p.L447= | Silent (SNP) | VAF 594/595 reads (100%) | called by muse, mutect2, varscan2
- GPR179 | c.522C>T p.I174= | Silent (SNP) | VAF 157/841 reads (19%) | catalogued as rs377062748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR75 | c.108C>A p.L36= | Silent (SNP) | VAF 182/671 reads (27%) | called by muse, mutect2, varscan2
- GRIN2A | c.3888C>T p.V1296= | Silent (SNP) | VAF 247/489 reads (51%) | catalogued as COSV58045800; called by muse, mutect2, varscan2
- HERC1 | c.6816G>A p.E2272= | Silent (SNP) | VAF 216/572 reads (38%) | catalogued as rs374040576; called by muse, mutect2, varscan2
- HGF | c.1305G>C p.L435= | Silent (SNP) | VAF 163/396 reads (41%) | catalogued as COSV55948213; called by muse, mutect2, varscan2
- HLTF | c.540C>T p.F180= | Silent (SNP) | VAF 169/892 reads (19%) | called by muse, mutect2, varscan2
- IMPG2 | c.315G>A p.V105= | Silent (SNP) | VAF 132/772 reads (17%) | catalogued as COSV99515441; called by muse, mutect2, varscan2
- ITGA1 | c.1641G>A p.Q547= | Silent (SNP) | VAF 170/502 reads (34%) | catalogued as COSV50876437; called by muse, mutect2, varscan2
- KCNA4 | c.1194C>G p.L398= | Silent (SNP) | VAF 200/388 reads (52%) | catalogued as rs545411525, COSV100069143; called by muse, mutect2, varscan2
- KCNH3 | c.2076C>T p.F692= | Silent (SNP) | VAF 314/642 reads (49%) | catalogued as rs751975762, COSV57791658; called by muse, mutect2, varscan2
- KCNH3 | c.3249C>T p.V1083= | Silent (SNP) | VAF 196/366 reads (54%) | called by muse, mutect2, varscan2
- KCNMB4 | c.54C>T p.I18= | Silent (SNP) | VAF 214/413 reads (52%) | called by muse, mutect2, varscan2
- KIAA0753 | c.438G>A p.R146= | Silent (SNP) | VAF 261/372 reads (70%) | catalogued as rs772573779; called by muse, varscan2
- KLHL1 | c.1636C>T p.L546= | Silent (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.815G>A p.*272= | Silent (SNP) | VAF 177/257 reads (69%) | catalogued as rs781818397; called by muse, mutect2, varscan2
- LAMA5 | c.10698G>A p.T3566= | Silent (SNP) | VAF 539/873 reads (62%) | catalogued as rs557901425, COSV53366009; called by muse, mutect2, varscan2
- LRRC9 | c.2874C>T p.L958= | Silent (SNP) | VAF 108/191 reads (57%) | called by muse, mutect2, varscan2
- LRRN1 | c.471T>C p.T157= | Silent (SNP) | VAF 188/371 reads (51%) | called by muse, mutect2, varscan2
- MACF1 | c.11163G>A p.Q3721= (on ENST00000372915; = p.Q1654= on NM_012090.5) | Silent (SNP) | VAF 143/205 reads (70%) | catalogued as COSV99245079; called by muse, mutect2, varscan2
- MAPK8IP1 | c.312C>T p.P104= | Silent (SNP) | VAF 312/735 reads (42%) | called by muse, mutect2, varscan2
- MOBP | c.183C>T p.I61= | Silent (SNP) | VAF 132/284 reads (46%) | catalogued as rs1474938306; called by muse, mutect2, varscan2
- MTCL1 | c.3336G>A p.Q1112= (on ENST00000306329 / NM_001378206.1; = p.Q793= on NM_015210.4) | Silent (SNP) | VAF 292/811 reads (36%) | catalogued as rs762212292, COSV60409931; called by muse, mutect2, varscan2
- MYO5C | c.1452G>A p.L484= | Silent (SNP) | VAF 165/450 reads (37%) | catalogued as COSV55913426; called by muse, mutect2, varscan2
- NDUFV1 | c.541C>T p.L181= | Silent (SNP) | VAF 182/514 reads (35%) | called by muse, mutect2
- NFATC2 | c.765G>A p.S255= | Silent (SNP) | VAF 346/977 reads (35%) | called by muse, mutect2, varscan2
- NFATC3 | c.2058G>A p.K686= | Silent (SNP) | VAF 65/371 reads (18%) | catalogued as rs753136816, COSV60477480; called by muse, mutect2, varscan2
- NPHS1 | c.2757A>G p.T919= | Silent (SNP) | VAF 209/763 reads (27%) | called by muse, mutect2, varscan2
- OLFML2A | c.1932C>G p.L644= | Silent (SNP) | VAF 336/447 reads (75%) | called by muse, mutect2, varscan2
- OR2K2 | c.633G>A p.A211= (on ENST00000374428; = p.A182= on NM_205859.2) | Silent (SNP) | VAF 253/324 reads (78%) | catalogued as rs777446444; called by muse, mutect2, varscan2
- OR6F1 | c.831G>A p.L277= | Silent (SNP) | VAF 153/382 reads (40%) | catalogued as COSV57469547; called by muse, mutect2, varscan2
- OR6K3 | c.253C>T p.L85= (on ENST00000368146; = p.L69= on NM_001005327.2) | Silent (SNP) | VAF 54/714 reads (8%) | catalogued as rs267598107, COSV63746443; called by muse, mutect2
- PCDH19 | c.1656C>A p.I552= | Silent (SNP) | VAF 324/325 reads (100%) | catalogued as COSV99718953; called by muse, mutect2, varscan2
- PCDHGB6 | c.1851C>T p.F617= | Silent (SNP) | VAF 219/467 reads (47%) | catalogued as COSV54051098; called by muse, mutect2, varscan2
- PDE7A | c.324C>T p.I108= (on ENST00000401827 / NM_001242318.3; = p.I82= on NM_002603.4) | Silent (SNP) | VAF 256/257 reads (100%) | catalogued as COSV65154019; called by muse, mutect2, varscan2
- PDIA5 | c.843G>A p.L281= | Silent (SNP) | VAF 106/846 reads (13%) | called by muse, mutect2, varscan2
- PER1 | c.291C>T p.S97= | Silent (SNP) | VAF 288/290 reads (99%) | catalogued as rs1211289187; called by muse, mutect2, varscan2
- PER2 | c.3195C>T p.L1065= | Silent (SNP) | VAF 208/418 reads (50%) | catalogued as rs1266653776; called by muse, mutect2, varscan2
- PGBD2 | c.1539C>T p.L513= | Silent (SNP) | VAF 230/577 reads (40%) | catalogued as rs1002181787; called by muse, mutect2, varscan2
- PLXNC1 | c.984C>A p.L328= | Silent (SNP) | VAF 378/744 reads (51%) | catalogued as rs1356018757; called by muse, mutect2, varscan2
- POSTN | c.1290G>A p.Q430= | Silent (SNP) | VAF 81/230 reads (35%) | called by muse, mutect2, varscan2
- PPP1R26 | c.9C>A p.L3= | Silent (SNP) | VAF 67/250 reads (27%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.1332C>A p.V444= | Silent (SNP) | VAF 110/301 reads (37%) | called by muse, mutect2, varscan2
- PSMD12 | c.96G>A p.A32= | Silent (SNP) | VAF 262/465 reads (56%) | catalogued as COSV62065163; called by muse, mutect2, varscan2
- PSPC1 | c.117C>T p.L39= | Silent (SNP) | VAF 312/502 reads (62%) | called by muse, mutect2, varscan2
- PTPRA | c.2142C>T p.A714= | Silent (SNP) | VAF 132/956 reads (14%) | catalogued as rs373557820; called by muse, mutect2, varscan2
- PTPRF | c.2997C>G p.L999= | Silent (SNP) | VAF 201/324 reads (62%) | called by muse, mutect2, varscan2
- PTPRF | c.3354C>G p.L1118= | Silent (SNP) | VAF 319/482 reads (66%) | called by muse, mutect2, varscan2
- PYHIN1 | c.375C>G p.L125= | Silent (SNP) | VAF 149/574 reads (26%) | called by muse, mutect2, varscan2
- RASGEF1C | c.48C>G p.L16= | Silent (SNP) | VAF 277/548 reads (51%) | called by muse, mutect2, varscan2
- RASGRF1 | c.1374G>C p.V458= | Silent (SNP) | VAF 62/349 reads (18%) | called by muse, mutect2, varscan2
- RGS3 | c.2994C>A p.L998= (on ENST00000350696 / NM_001282923.2; = p.L717= on NM_130795.4) | Silent (SNP) | VAF 245/329 reads (74%) | called by muse, mutect2, varscan2
- RNF135 | c.885G>A p.E295= | Silent (SNP) | VAF 90/538 reads (17%) | catalogued as COSV60434715; called by muse, mutect2, varscan2
- RPL10L | c.66C>T p.F22= | Silent (SNP) | VAF 107/394 reads (27%) | catalogued as rs1051801955; called by muse, mutect2, varscan2
- SAP130 | c.1680G>T p.G560= | Silent (SNP) | VAF 222/434 reads (51%) | catalogued as rs576991787; called by muse, mutect2, varscan2
- SCN3A | c.1473G>A p.L491= | Silent (SNP) | VAF 171/330 reads (52%) | catalogued as COSV51801672; called by muse, mutect2, varscan2
- SELP | c.1395C>T p.F465= | Silent (SNP) | VAF 63/665 reads (9%) | catalogued as rs148376334; called by muse, mutect2
- SERPINF1 | c.141C>T p.F47= | Silent (SNP) | VAF 99/461 reads (21%) | called by muse, mutect2, varscan2
- SHOX | c.738C>T p.F246= | Silent (SNP) | VAF 360/363 reads (99%) | catalogued as rs771336598, COSV61860775; called by muse, mutect2, varscan2
- SIRT2 | c.1140C>T p.A380= | Silent (SNP) | VAF 229/4683 reads (5%) | called by muse, mutect2
- SKI | c.921G>A p.V307= | Silent (SNP) | VAF 115/301 reads (38%) | catalogued as rs1557807513; called by muse, mutect2, varscan2
- SLAMF9 | c.300G>C p.L100= | Silent (SNP) | VAF 76/642 reads (12%) | called by muse, mutect2, varscan2
- SLC2A5 | c.1401G>A p.T467= | Silent (SNP) | VAF 75/283 reads (27%) | catalogued as rs375528725; called by muse, mutect2, varscan2
- SLC30A10 | c.627C>T p.F209= | Silent (SNP) | VAF 153/409 reads (37%) | catalogued as rs925558667; called by muse, mutect2, varscan2
- SLITRK5 | c.939G>A p.V313= | Silent (SNP) | VAF 200/306 reads (65%) | called by muse, mutect2, varscan2
- SMCHD1 | c.5700G>C p.L1900= | Silent (SNP) | VAF 67/506 reads (13%) | catalogued as rs762736228; called by muse, mutect2, varscan2
- SRPK2 | c.477G>C p.G159= | Silent (SNP) | VAF 119/300 reads (40%) | catalogued as COSV61958878; called by muse, mutect2, varscan2
- STAT4 | c.918C>T p.F306= | Silent (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- STXBP5L | c.249A>G p.K83= | Silent (SNP) | VAF 48/505 reads (10%) | catalogued as rs375513651; called by muse, mutect2, varscan2
- SWSAP1 | c.474C>T p.L158= (on ENST00000312423; = p.L179= on NM_175871.4) | Silent (SNP) | VAF 162/449 reads (36%) | called by muse, mutect2, varscan2
- SYT17 | c.1275C>A p.I425= | Silent (SNP) | VAF 271/347 reads (78%) | catalogued as rs780389431, COSV62547550; called by muse, mutect2, varscan2
- TARS2 | c.1383C>T p.I461= | Silent (SNP) | VAF 48/610 reads (8%) | catalogued as rs1470254633, COSV64696771; called by muse, mutect2
- TBCA | c.15C>T p.R5= | Silent (SNP) | VAF 101/310 reads (33%) | called by muse, mutect2, varscan2
- TERF2 | c.990G>A p.L330= | Silent (SNP) | VAF 139/413 reads (34%) | called by muse, mutect2, varscan2
- TFB2M | c.93G>A p.A31= | Silent (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- TFRC | c.1626C>T p.F542= | Silent (SNP) | VAF 110/612 reads (18%) | called by muse, mutect2, varscan2
- THOC5 | c.1203G>C p.L401= | Silent (SNP) | VAF 156/477 reads (33%) | called by muse, mutect2, varscan2
- TIRAP | c.183C>G p.L61= | Silent (SNP) | VAF 353/354 reads (100%) | called by muse, mutect2, varscan2
- TKTL2 | c.705G>A p.V235= | Silent (SNP) | VAF 325/444 reads (73%) | called by muse, mutect2, varscan2
- TLE7 | c.1065C>T p.F355= | Silent (SNP) | VAF 211/583 reads (36%) | called by muse, mutect2, varscan2
- TLR6 | c.2013T>A p.I671= | Silent (SNP) | VAF 247/319 reads (77%) | called by muse, mutect2, varscan2
- TMEM45A | c.300C>T p.F100= | Silent (SNP) | VAF 171/901 reads (19%) | called by muse, mutect2, varscan2
- TTC21A | c.3606G>A p.K1202= | Silent (SNP) | VAF 213/450 reads (47%) | called by muse, mutect2, varscan2
- UHRF2 | c.711G>A p.L237= | Silent (SNP) | VAF 33/484 reads (7%) | called by muse, mutect2
- ULK4 | c.30C>T p.I10= | Silent (SNP) | VAF 114/253 reads (45%) | catalogued as rs371284862; called by muse, mutect2, varscan2
- UMPS | c.549C>G p.L183= | Silent (SNP) | VAF 77/699 reads (11%) | catalogued as rs913514809, COSV51736164; called by muse, mutect2, varscan2
- USH1G | c.577C>T p.L193= | Silent (SNP) | VAF 134/764 reads (18%) | called by muse, mutect2, varscan2
- USP34 | c.3625C>T p.L1209= | Silent (SNP) | VAF 132/533 reads (25%) | catalogued as rs1165595644; called by muse, mutect2, varscan2
- USP43 | c.399C>G p.R133= | Silent (SNP) | VAF 147/606 reads (24%) | called by muse, mutect2, varscan2
- XRCC6 | c.1119G>A p.S373= | Silent (SNP) | VAF 82/406 reads (20%) | catalogued as rs772870059; called by muse, mutect2, varscan2
- XRN1 | c.60G>A p.V20= | Silent (SNP) | VAF 160/1092 reads (15%) | catalogued as rs760460549; called by muse, mutect2, varscan2
- ZDHHC8 | c.1260C>T p.L420= | Silent (SNP) | VAF 268/1244 reads (22%) | catalogued as rs1413624657; called by muse, mutect2, varscan2
- ZFYVE9 | c.3216C>T p.I1072= | Silent (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- ZMYND15 | c.975G>A p.L325= | Silent (SNP) | VAF 231/311 reads (74%) | called by muse, mutect2, varscan2
- ZNF280A | c.1287C>G p.L429= | Silent (SNP) | VAF 229/856 reads (27%) | catalogued as COSV100131135; called by muse, mutect2, varscan2
- ZNF431 | c.816C>G p.S272= | Silent (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2, varscan2
- ZNF749 | c.552G>A p.Q184= | Silent (SNP) | VAF 152/257 reads (59%) | catalogued as COSV99043271; called by muse, mutect2, varscan2
- AGTR1 | c.-47-10757G>A | Intron (SNP) | VAF 46/844 reads (5%) | catalogued as rs936459917; called by muse, mutect2
- AMDHD2 | c.971-19T>A | Intron (SNP) | VAF 513/672 reads (76%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.355+27227G>C | Intron (SNP) | VAF 118/319 reads (37%) | catalogued as COSV100597038; called by muse, mutect2, varscan2
- CD55 | c.*9G>A | 3'UTR (SNP) | VAF 36/318 reads (11%) | called by muse, mutect2, varscan2
- COX5A | c.*102G>C | 3'UTR (SNP) | VAF 113/328 reads (34%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.2906+4900G>A | Intron (SNP) | VAF 43/484 reads (9%) | called by muse, mutect2, varscan2
- MAGI2 | c.3706+44G>A | Intron (SNP) | VAF 49/350 reads (14%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3430G>C | Intron (SNP) | VAF 214/215 reads (100%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640592 G>C | 3'Flank (SNP) | VAF 114/631 reads (18%) | catalogued as COSV51706017; called by muse, mutect2, varscan2
- MIR9-1HG | n.485C>G | RNA (SNP) | VAF 125/437 reads (29%) | catalogued as rs757842789; called by muse, mutect2, varscan2
- SKP2 | c.*1945G>A | 3'UTR (SNP) | VAF 98/399 reads (25%) | called by muse, varscan2
- TMEM105 | n.861C>T | RNA (SNP) | VAF 125/624 reads (20%) | called by muse, mutect2, varscan2
- WASL | c.-167C>T | 5'UTR (SNP) | VAF 96/554 reads (17%) | catalogued as COSV99771685; called by muse, mutect2, varscan2
- ZDHHC11B | c.*1G>C | 3'UTR (SNP) | VAF 104/1400 reads (7%) | called by muse, mutect2
